Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A6M7, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A6M7-01A (Primary Tumor).

[page 1 of 4]
Gender M

Date Of Birth

Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Received

Time Reported

Order Number

Ordering Provider

Status

Final

Results

Final

Source of Specimen

A. TISSUE OVER PROSTATE-

B. PROSTATE GLAND SEMINAL VESICLES AND VAS DEFERENS-

FINAL DIAGNOSIS:

A. TISSUE OVER PROSTATE-

FATTY TISSUE, NO TUMOR SEEN.

B. PROSTATE GLAND SEMINAL VESICLES AND VAS DEFERENS-

ADENOCARCINOMA OF PROSTATE. NO EXTRAPROSTATIC EXTENSION SEEN.

TUMOR SITE: RIGHT AND LEFT PROSTATE, MOSTLY IN PERIPHERAL AND TRANSITIONAL ZONES.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 50 GRAMS. SIZE: 4 x 4 x 4 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 4 = 7/10.

TERTIARY PATTERN: NOT SEEN.

SEVERITY IN EXTENT OF TUMOR: 3/5.

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): PRESENT, AT LEAST 1.5 CM IN SIZE.

TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

Prepared for

CCP ID-0-3
Adenocarcinoma, acinar
8/40/3
path
Adenocarcinoma, NOS
8/40/3
Site Prostate NOS
6/19
7/24/13

[page 2 of 4]
TNM STAGE: pT2c, pNX, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT SPECIMEN MARGINS.

Signature

(Case signed

Case Clinical Information

PROSTATE CANCER

Gross Description

A. Received in formalin labeled with the patient's name and "tissue over prostate" are fragmented fatty lobules measuring 2 x 2 x 2 cm in compact aggregate. All material submitted in A1-A2.

B. Received in formalin labeled with the patient's name and "prostate gland seminal vesicles and vas deferens" is a 50 gram specimen to include a previously partially bisected prostate measuring 4 cm superior to inferior, 4 cm right to left, 4 cm anterior to posterior. The right seminal vesicle and vas measure 2.5 x 2 x 1.3 cm and 2.2 x 0.3 cm. The left seminal vas measures 2.5 x 1.5 x 0.8 cm and 4 x 0.3 cm. The right side of the specimen has been previously inked blue, left side black. The bladder aspect of the prostate is somewhat disrupted. The distal urethral margin and proximal bladder margin are amputated from the remainder of the specimen shall be serially cross sectioned anterior to posterior parallel to the plane of the urethra and totally submitted. The remaining gland shows firm focally nodular parenchyma. Section code: distal prostatic margin totally submitted anterior to posterior B1-B4; complete slice mid gland, anterior lobes B5-B6; posterior lobes B7-B9; complete section upper third of gland, anterior lobes B10-B11; posterior B12-B14; remaining posterior lobes in B15-B18; proximal bladder margin totally submitted anterior to posterior B19-B23; left seminal vesicle and vas B24; right seminal vesicle and vas B25.

Physicians

Prepared for

[page 3 of 4]
Procedure

A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
B. AA ROUTINE H&E X1 BLOCK.3
H&E X1
B. AA ROUTINE H&E X1 BLOCK.4
H&E X1
B. AA ROUTINE H&E X1 BLOCK.5
H&E X1
B. AA ROUTINE H&E X1 BLOCK.6
H&E X1
B. AA ROUTINE H&E X1 BLOCK.7
H&E X1
B. AA ROUTINE H&E X1 BLOCK.8
H&E X1
B. AA ROUTINE H&E X1 BLOCK.9
H&E X1
B. AA ROUTINE H&E X1 BLOCK.10
H&E X1
B. AA ROUTINE H&E X1 BLOCK.11
H&E X1
B. AA ROUTINE H&E X1 BLOCK.12
H&E X1
B. AA ROUTINE H&E X1 BLOCK.13
H&E X1
B. AA ROUTINE H&E X1 BLOCK.14
H&E X1
B. AA ROUTINE H&E X1 BLOCK.15
H&E X1
B. AA ROUTINE H&E X1 BLOCK.16
H&E X1
B. AA ROUTINE H&E X1 BLOCK.17
H&E X1
B. AA ROUTINE H&E X1 BLOCK.18
H&E X1
B. AA ROUTINE H&E X1 BLOCK.19
H&E X1
B. AA ROUTINE H&E X1 BLOCK.20
H&E X1
B. AA ROUTINE H&E X1 BLOCK.21

Prepared for

[page 4 of 4]
H&E X1
B. AA ROUTINE H&E X1 BLOCK.22
H&E X1
B. AA ROUTINE H&E X1 BLOCK.23
H&E X1
B. AA ROUTINE H&E X1 BLOCK.24
H&E X1
B. AA ROUTINE H&E X1 BLOCK.25
H&E X1

Source: NCI Genomic Data Commons file 1839549f-071c-49c1-9fff-f3e2fe45e56d (TCGA-J4-A6M7.F717DD9D-074A-4252-9125-C00A3DE587B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).